Somatic mutation profile of tumor specimen 0DVZ16 from CCDI case PBCMZG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Sertoli-Leydig cell tumor, poorly differentiated; Tissue or organ of origin: Ovary; Age at diagnosis: 15.2 years (5,551 days).
Specimen 0DVZ16: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7a73b7f2-cc76-4028-9dbd-561deb57f801.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVZ0M (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7c80f44e-7794-4440-a8d3-2da4866fd140

The open-access MAF lists 5 somatic variants for this specimen: 5 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3, Translation Start Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DICER1 | c.5437G>A p.E1813K | Missense Mutation (SNP) | VAF 244/811 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as CM160050, COSV58615431, COSV58617855; called by muse, mutect2, varscan2
- HEPH | c.1567C>T p.P523S (on ENST00000343002; = p.P256S on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 142/509 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as rs745729965; called by muse, mutect2, varscan2
- MAGEC1 | c.1952C>G p.P651R | Missense Mutation (SNP) | VAF 47/287 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.177); catalogued as rs1220509333; called by muse, mutect2, varscan2
- CLVS2 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 100/457 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- LRSAM1 | c.1285del p.Q429Sfs*34 | Frame Shift Del (DEL) | VAF 54/246 reads (22%) | called by mutect2, varscan2
